CCDI case PBBMIX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/79b61129-2083-4e65-82ea-2ee937b70844

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (583 days).

Biospecimens (4 samples)
- Sample 0DCWB4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCWB9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DCWBF, 0DCYNI (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
